Gene-level copy-number profile of tumor specimen TCGA-JX-A3Q8-01A from TCGA case TCGA-JX-A3Q8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 40.6 years (14,839 days).
Specimen TCGA-JX-A3Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.4f3a6d35-d6cb-43ac-b6bb-04f6f1cd9297.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JX-A3Q8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9634d690-4527-40e1-8b6f-ff23d9598e71

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 98; copy number 2: 14,937; copy number 3: 24,296; copy number 4: 17,725; copy number 5: 2,708; copy number 6: 8; copy number 7: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JX-A3Q8-01A-11D-A21P-01): tumor purity 0.86, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,960,658–4,594,016, 40 genes: AL589702.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104, DFFB, C1orf174, LINC01134, LINC01346, LINC01345, LINC02780, AL805961.1, EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:26,008,940–26,477,840, 6 genes, copy number 7: AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2.
- chr15:26,557,598–26,658,763, 2 genes, copy number 7: AC009878.1, AC011196.1.

Autosomal genes at a single copy (total copy number 1): 98. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
